MMRF case MMRF_1640 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eb8a41f8-8e60-43fc-9013-284c9f012c9e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.7 years (26,173 days); ISS stage: III; Days to last known disease status: 1,219 days (3.3 years); Days to last follow up: 1,219 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 34 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 136 days; Days to treatment end: 136 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 137 days; Days to treatment end: 137 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10300 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 7.88 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 282 ×10⁹/L.
- Day 107 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.23 mg/dL; Immunoglobulin G 3.68 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.68 µg/mL; Lactate Dehydrogenase 6.62 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 20.2 ×10⁹/L; Absolute Neutrophil 18.7 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.98 mmol/L; Albumin 29 g/L; Total Protein 5.1 g/dL; Glucose 5.56 mmol/L.
- Day 199 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 3.97 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.68 mmol/L; Albumin 30 g/L; Total Protein 4.6 g/dL; Glucose 4.02 mmol/L.
- Day 276 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.61 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 337 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 9.95 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 8.5 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 6.22 mmol/L.
- Day 451 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 6.7 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.46 mmol/L.
- Day 542 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 7.89 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 4.68 mmol/L.
- Day 633 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 9.92 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 6.93 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.78 mmol/L.
- Day 730 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 821 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 6.16 mmol/L.
- Day 918 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.52 mg/dL; Immunoglobulin G 9.51 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.94 mmol/L.
- Day 1,037 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 9.86 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.05 mmol/L.
- Day 1,128 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.61 mmol/L.
- Day 1,219 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 9.71 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 6.49 mmol/L.

Other clinical attributes
- Day 1: Weight: 67 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1640_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1640_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
